Gene-level copy-number profile of tumor specimen TCGA-BA-6870-01A from TCGA case TCGA-BA-6870, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 60.8 years (22,222 days).
Specimen TCGA-BA-6870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f84c563e-cad2-4062-ab06-96141e709542.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-6870-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f46be6b5-2a89-432b-a06d-677ec73c5ae3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 746; copy number 2: 8,742; copy number 3: 19,855; copy number 4: 17,896; copy number 5: 2,713; copy number 6: 8,132; copy number 7: 325; copy number 8: 709; copy number 9: 409; copy number 10: 4; copy number 12: 72; copy number 14: 37; copy number 18: 71; copy number 21: 60; copy number 23: 29; copy number 35: 7; copy number 40: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-6870-01A-11D-1869-01): tumor purity 0.32, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,272,309–11,557,665, 1 gene (within-gene range 0–2): ATG7.
- chr3:11,488,300–11,771,350, 5 genes (within-gene range 0–2): AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr3:61,561,569–62,297,609, 1 gene (within-gene range 0–2): PTPRG.
- chr3:62,118,300–62,124,608, 2 genes: RNU2-10P, ID2B.
- chr8:4,317,388–4,329,027, 1 gene: AC027251.1.
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,724 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–34,373,850, 525 genes, copy number 8 (broad region; genes not listed).
- chr7:3,301,252–4,269,000, 1 gene, copy number 9 (within-gene range 2–9): SDK1.
- chr7:3,642,815–5,781,696, 43 genes, copy number 9 (within-gene range 6–9): AC011284.1, AC017000.1, CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874.
- chr7:27,412,164–34,299,012, 119 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:134,527,567–134,579,875, 2 genes, copy number 7: AKR1B10, AKR1B15.
- chr8:35,080,592–38,601,200, 76 genes, copy number 10–40 (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 8 (within-gene range 5–8): AP003071.5.
- chr11:69,103,493–73,397,474, 146 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:73,405,297–73,410,682, 1 gene, copy number 8: AP000763.3.
- chr11:100,641,975–104,609,498, 67 genes, copy number 21–35 (within-gene range 1–35) (broad region; genes not listed).
- chr12:62,643,994–62,935,150, 1 gene, copy number 9 (within-gene range 5–9): PPM1H.
- chr12:62,755,227–71,710,374, 197 genes, copy number 9–23 (broad region; genes not listed).
- chr14:21,918,188–22,508,658, 81 genes, copy number 7 (broad region; genes not listed).
- chr14:48,394,815–48,491,767, 1 gene, copy number 14 (within-gene range 4–14): AL358335.2.
- chr14:48,489,883–57,994,525, 204 genes, copy number 7–14 (broad region; genes not listed).
- chr19:23,222,755–23,274,221, 1 gene, copy number 8 (within-gene range 6–8): AC092329.3.
- chr19:23,255,053–24,163,425, 35 genes, copy number 8: IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:37,178,410–45,972,203, 223 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
